CCDI case PBCAGR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1b2c5b9f-466b-4d7e-a55a-48948bb62bd5

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.8 years (2,835 days).

Biospecimens (3 samples)
- Sample 0DMKB2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKB3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMKB4: Tissue type: Tumor; Specimen type: Solid Tissue.
